Gene-level copy-number profile of tumor specimen TCGA-FD-A6TK-01A from TCGA case TCGA-FD-A6TK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 60.1 years (21,942 days).
Specimen TCGA-FD-A6TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.647c4fab-16bf-4930-ab33-ee2a7d829efa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14fee90b-bbb3-4f00-8241-74f15192ae57

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 34,247; copy number 2: 24,044; copy number 3: 1,521.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TK-01A-42D-A338-01): tumor purity 0.22, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,521 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,855,970–4,147,429, 27 genes, copy number 3: LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr5:6,839,460–7,219,291, 1 gene, copy number 3 (within-gene range 2–3): LINC02196.
- chr5:7,047,227–45,895,970, 572 genes, copy number 3 (broad region; genes not listed).
- chr7:122,994,704–123,230,741, 4 genes, copy number 3: TAS2R16, AC073311.1, SLC13A1, LYPLA1P1.
- chr8:65,526,738–70,790,371, 93 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr8:79,259,402–80,930,081, 41 genes, copy number 3: AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1.
- chr8:96,261,902–97,149,654, 8 genes, copy number 3: PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1.
- chr8:98,371,228–98,942,827, 1 gene, copy number 3 (within-gene range 1–3): STK3.
- chr8:98,412,882–145,066,685, 740 genes, copy number 3 (broad region; genes not listed).
- chr19:27,638,483–29,015,160, 34 genes, copy number 3: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.

Autosomal genes at a single copy (total copy number 1): 31,868. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
